FM case AD5477 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/37b1b713-d841-49ba-9603-c582df6bd9ed

Female, 48.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the rectum; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
